CCDI case PBCIAW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4ce0abf3-9291-4bcd-84b7-4e5664d13a82

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.9 years (1,430 days).

Biospecimens (3 samples)
- Sample 0DSJXX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSJY6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSJYJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
